Somatic mutation profile of tumor specimen 0DVR7U from CCDI case PBCFHE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 7.3 years (2,674 days).
Specimen 0DVR7U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dde236b-bc8d-4313-a5f1-ea890b2c3896.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVR5P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4af4bc5c-2b7f-4f9a-98ed-33ab536ef6ed

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL1 | c.4274C>A p.T1425N (on ENST00000340736 / NM_001008701.3; = p.T1420N on NM_014921.5) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.309); called by muse, varscan2
- MMS22L | c.3115C>T p.P1039S | Missense Mutation (SNP) | VAF 87/422 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TBC1D10A | c.418-60T>C | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- VAX2 | c.*63G>A | 3'UTR (SNP) | VAF 4/35 reads (11%) | catalogued as rs782062876; called by muse, mutect2, varscan2
